Somatic mutation profile of tumor specimen TCGA-76-6664-01A (aliquot TCGA-76-6664-01A-11D-1845-08) from TCGA case TCGA-76-6664, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.4 years (18,054 days).
Specimen TCGA-76-6664-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 937e5e43-c1be-4bab-bcf6-73c40f183fe2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-6664-10A (Blood Derived Normal), aliquot TCGA-76-6664-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bffc3787-ea5a-4648-b9a3-2c073e0a9f86

The open-access MAF lists 52 somatic variants for this specimen: 36 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, Nonsense Mutation 3, Splice Site 3, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.254-2A>C p.X85_splice | Splice Site (SNP) | VAF 23/54 reads (43%) | hotspot (GDC flag); catalogued as COSV100911416, COSV64300109; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 25/75 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AIFM3 | c.1400A>T p.D467V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53149066; called by muse, mutect2, varscan2
- ANGPTL5 | c.1119A>T p.K373N | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57533745; called by muse, mutect2, varscan2
- AQR | c.2018T>C p.I673T | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50040729; called by muse, mutect2, varscan2
- ARFGEF2 | c.4750G>A p.A1584T | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs201449025, COSV64212460; called by muse, mutect2, varscan2
- ASB2 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs113529772, COSV60111246, COSV60113216; called by muse, mutect2, varscan2
- ATP7A | c.3715G>T p.A1239S | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV58449432; called by muse, mutect2, varscan2
- B4GALT2 | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as rs757515250, COSV52544123; called by muse, mutect2, varscan2
- CFP | c.887G>C p.C296S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55950786; called by muse, mutect2, varscan2
- CNGB3 | c.903+1G>A p.X301_splice | Splice Site (SNP) | VAF 11/79 reads (14%) | catalogued as rs1440619177, COSV60693274; called by muse, mutect2, varscan2
- DDX18 | c.1845C>A p.F615L | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV54305597, COSV54307549; called by muse, mutect2, varscan2
- ERN2 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs201055598, COSV56835449; called by muse, mutect2, varscan2
- GAPVD1 | c.2098G>A p.D700N | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV52924950; called by muse, mutect2, varscan2
- GPRASP2 | c.334A>G p.T112A | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV59991933; called by muse, mutect2, varscan2
- IPO8 | c.1912C>T p.R638W | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs776148047, COSV56243382; called by muse, mutect2, varscan2
- IQCG | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372501872; called by muse, mutect2, varscan2
- JAG2 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs775767402, COSV59306892; called by muse, mutect2, varscan2
- MAOB | c.1336G>C p.A446P | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65206116; called by muse, varscan2
- MIER2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs780727112, COSV53394228; called by muse, mutect2, varscan2
- MMP1 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778882706, COSV59510951; called by muse, mutect2, varscan2
- MYH1 | c.5269G>C p.E1757Q | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56852295; called by muse, mutect2, varscan2
- NOX4 | c.1446+2T>A p.X482_splice | Splice Site (SNP) | VAF 44/150 reads (29%) | catalogued as COSV54458364; called by muse, varscan2
- NPFFR2 | c.10T>A p.F4I | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV58151620; called by muse, mutect2, varscan2
- OR2B6 | c.473G>T p.W158L | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV55129324; called by muse, mutect2, varscan2
- PNLDC1 | c.1290G>A p.W430* | Nonsense Mutation (SNP) | VAF 40/117 reads (34%) | catalogued as COSV51706499; called by muse, mutect2, varscan2
- PNPLA4 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as rs372843326, CM161321, COSV66854267; called by muse, mutect2, varscan2
- PPM1J | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs201845248, COSV58552365; called by muse, mutect2, varscan2
- ROPN1L | c.520T>G p.Y174D | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56874291; called by muse, mutect2, varscan2
- SAMD9 | c.4765G>C p.V1589L | Missense Mutation (SNP) | VAF 59/235 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV66076528; called by muse, mutect2, varscan2
- STARD13 | c.2587G>T p.E863* (on ENST00000336934 / NM_001243476.3; = p.E745* on NM_052851.3) | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV55233400; called by muse, mutect2, varscan2
- TMF1 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 97/341 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs771579360, COSV68374033; called by muse, mutect2, varscan2
- TMPRSS15 | c.2999G>A p.R1000H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.191); catalogued as rs192022515, COSV53040788; called by muse, mutect2, varscan2
- TMSB15A | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV56818445; called by muse, mutect2, varscan2
- VCAN | c.2551G>A p.A851T | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs1480597677, COSV54110243; called by muse, mutect2, varscan2
- CBLN1 | c.63del p.Q22Rfs*56 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | called by mutect2, pindel, varscan2
- ADAMTS2 | c.2541C>T p.N847= | Silent (SNP) | VAF 45/143 reads (31%) | catalogued as rs1436992389, COSV52364795, COSV52366033, COSV99283334; called by muse, mutect2, varscan2
- DCAF15 | c.1608G>C p.L536= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV54331335; called by muse, mutect2, varscan2
- DMRT3 | c.1284C>T p.R428= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as rs764166688, COSV51902493; called by muse, mutect2, varscan2
- FAM181B | c.1173G>A p.V391= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs768526134, COSV61300797; called by muse, mutect2, varscan2
- FAM234A | c.1656G>A p.A552= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs200499463; called by muse, mutect2, varscan2
- KCNK3 | c.288C>T p.Y96= | Silent (SNP) | VAF 83/245 reads (34%) | catalogued as rs747452070, COSV57193400; called by muse, mutect2, varscan2
- MMP9 | c.753C>T p.D251= | Silent (SNP) | VAF 41/145 reads (28%) | catalogued as rs1458661026, COSV63434241; called by muse, mutect2, varscan2
- MUC16 | c.2304C>T p.A768= | Silent (SNP) | VAF 66/295 reads (22%) | catalogued as rs745612296, COSV67478377; called by muse, mutect2, varscan2
- PRPS1L1 | c.768A>T p.P256= | Silent (SNP) | VAF 48/173 reads (28%) | catalogued as COSV72649939; called by muse, mutect2, varscan2
- SLC15A1 | c.1962G>A p.A654= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs143994270; called by muse, mutect2, varscan2
- SMS | c.465G>A p.S155= | Silent (SNP) | VAF 41/138 reads (30%) | catalogued as rs1261897927, COSV65114732; called by muse, mutect2, varscan2
- THBS1 | c.1137C>T p.D379= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs866787040, COSV52953780; called by muse, mutect2, varscan2
- TUBB4A | c.909C>T p.C303= | Silent (SNP) | VAF 61/215 reads (28%) | catalogued as rs1282533762, COSV51159584; called by muse, mutect2, varscan2
- XRN2 | c.2764C>A p.R922= | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as rs778993983, COSV65870526; called by muse, mutect2, varscan2
- BIN1 | c.858-1454A>G | Intron (SNP) | VAF 13/49 reads (27%) | catalogued as rs1372826115, COSV99387834; called by muse, mutect2, varscan2
- SEPTIN9 | c.722-6505_722-6504del | Intron (DEL) | VAF 10/46 reads (22%) | called by pindel, varscan2
